Gene-level copy-number profile of tumor specimen AP-RA2G-6Y from APOLLO case AP-RA2G, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3.
Specimen AP-RA2G-6Y: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 106637c4-7611-4fcb-bbd4-09cbad4880a4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-RA2G-AL (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/8eb5dd97-f75f-4828-98d9-c2fcb018abbc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,612; copy number 2: 16,400; copy number 3: 20,257; copy number 4: 8,772; copy number 5: 7,904; copy number 6: 1,329; copy number 7: 218; copy number 8: 174; copy number 9: 367; copy number 10: 150; copy number 11: 22; copy number 12: 108; copy number 13: 18; copy number 14: 11; copy number 15: 14; copy number 18: 6; copy number 22: 32.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,120 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:195,650,146–195,741,123, 7 genes, copy number 7: AC233280.2, AC233280.1, MUC20-OT1, SDHAP2, MIR570, SMBD1P, MUC20.
- chr3:197,634,315–197,635,811, 1 gene, copy number 7: AC024560.2.
- chr4:33,010,948–33,693,993, 5 genes, copy number 7–11: MAPRE1P2, AC093878.1, AC097535.2, AC097535.1, AC079772.1.
- chr6:132,816,802–133,532,128, 11 genes, copy number 8–11 (within-gene range 2–11): SNORD100, SNORA33, HMGB1P13, AL137783.1, LINC00326, RPL23AP46, AL591115.1, MTCYBP4, EYA4, AL024497.1, AL024497.2.
- chr6:133,510,386–133,510,693, 1 gene, copy number 11 (within-gene range 2–11): HSPE1P21.
- chr6:139,028,745–139,043,302, 1 gene, copy number 8: ABRACL.
- chr6:143,060,496–144,853,034, 34 genes, copy number 11–15: AIG1, AL023581.1, AL136116.2, AL136116.1, AL136116.3, AL031320.1, ADAT2, TUBB8P2, RNA5SP221, PEX3, AL031320.2, VDAC1P8, FUCA2, PHACTR2, PHACTR2-AS1, AL049844.1, LTV1, AL049844.3, AL049844.2, ZC2HC1B, PLAGL1, HYMAI, AL109755.2, AL109755.1, SF3B5, MRPL42P3, STX11, TPT1P4, AL024474.1, UTRN, AL024474.2, AL590704.1, AL513475.1, AL513475.2.
- chr7:37,032–33,877,180, 576 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr7:51,471,717–57,020,273, 109 genes, copy number 7–8 (broad region; genes not listed).
- chr7:63,087,070–63,456,687, 29 genes, copy number 7: ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1, AC092001.1, PHKG1P1, AC006455.8, SEPTIN7P4, AC006455.7, ZNF733P, AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4, VN1R31P, VN1R32P, AC073188.3, AC073188.4, AC073188.2, AC073188.1, AC073188.5, AC073188.6, SLC25A1P2, VN1R33P, ARAFP2, ZNF734P.
- chr8:46,028,804–46,028,892, 1 gene, copy number 9: AC118650.1.
- chr8:59,119,040–60,967,775, 24 genes, copy number 12–18 (within-gene range 6–18): AC090152.1, AC087698.1, RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1, AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, IFITM3P8, AC022182.1, NASPP1, AC022182.2.
- chr8:63,651,457–66,197,315, 32 genes, copy number 22 (within-gene range 5–22): AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8, MIR124-2HG, MIR124-2, AC090136.1, AC090136.2, AC090136.3, BHLHE22, CYP7B1, AC104232.2, AC104232.3, AC104232.1, AC087808.1, RPL31P41, LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967.
- chr14:30,734,926–30,895,065, 6 genes, copy number 12 (within-gene range 3–12): AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3.
- chr14:34,752,731–37,596,059, 69 genes, copy number 12–14 (within-gene range 4–14) (broad region; genes not listed).
- chr14:48,045,481–48,046,216, 1 gene, copy number 10: AL359212.1.
- chr14:55,124,110–56,816,693, 36 genes, copy number 10 (within-gene range 6–10): LGALS3, DLGAP5, AL139316.1, AL158801.4, COX5AP1, AL158801.2, FBXO34, AL158801.1, Metazoa_SRP, CHMP4BP1, AL158801.3, ATG14, HMGN1P1, TBPL2, RPL21P6, KTN1-AS1, RPL7AP4, ABI1P1, KTN1, Y_RNA, AL355773.1, RPL13AP3, LINC00520, AL163952.1, AL138995.1, PELI2, AL355073.1, AL355073.2, LINC02284, TMEM260, AL355103.1, AL161757.2, AL161757.5, AL161757.1, AL161757.3, OTX2.
- chr14:59,135,488–59,136,421, 1 gene, copy number 8: AKR1B1P5.
- chr14:60,091,911–61,550,976, 31 genes, copy number 8 (within-gene range 3–8): PCNX4, DHRS7, SCOCP1, PSMA3P1, RPL17P2, AL157756.1, PPM1A, LINC02322, C14orf39, RBM8B, GNRHR2P1, SALL4P7, SIX6, AL049874.3, AL049874.4, AL049874.2, AL049874.1, SALRNA1, SIX1, SIX4, MNAT1, MAD2L1P1, AL160236.2, SRMP2, TRMT5, AL160236.1, RNU6-398P, SLC38A6, PRKCH, TMEM30B, AL359220.1.
- chr19:1,438,358–1,479,219, 5 genes, copy number 13: RPS15, AC027307.3, APC2, AC027307.2, C19orf25.
- chr20:31,465,506–32,003,387, 26 genes, copy number 7: DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2.
- chr20:51,386,957–56,368,663, 53 genes, copy number 7–14: NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B.
- chr21:13,038,160–15,067,837, 61 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,612. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
